CPTAC case C3N-01003 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/14d9e460-63cb-43e4-b323-fee2bb408eab

Demographics
Sex at birth: female; Race: white; Year of birth: 1943; Vital status: Dead; Days to death: 759 days (2.1 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 73.9 years (26,984 days); Year of diagnosis: 2016; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVB; FIGO stage: Stage IVB; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 759 days (2.1 years); Progression or recurrence: yes; Days to last follow up: 606 days (1.7 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 6; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 174 days; Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 606 days (1.7 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 440 days (1.2 years); Karnofsky performance status: 60; ECOG performance status: 2.

Other clinical attributes
- Weight: 86 kg; Height: 164 cm; BMI: 31; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01003-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 257 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01003-21: Section location: Anterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-01003-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 123 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01003-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01003-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
